Somatic mutation profile of tumor specimen ALCH-B04P-TTP1-A (aliquot ALCH-B04P-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B04P, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.4 years (22,775 days).
Specimen ALCH-B04P-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 248e2948-1227-4753-84af-153c4940d74a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B04P-NB1-A (Blood Derived Normal), aliquot ALCH-B04P-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a930387-6d9c-45b7-8bcd-a5b48fb4c418

The open-access MAF lists 192 somatic variants for this specimen: 134 protein-altering or splice-affecting, 35 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 35, Intron 11, Nonsense Mutation 9, RNA 6, Frame Shift Del 5, Splice Site 5, 5'UTR 4, Splice Region 3, 3'UTR 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 142/763 reads (19%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.401T>G p.F134C | Missense Mutation (SNP) | VAF 42/204 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780442292, CM083195, COSV52669400, COSV52722353; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6244T>A p.F2082I (on ENST00000272895 / NM_173076.3; = p.F1764I on NM_015657.3) | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55959179; called by muse, mutect2, varscan2
- ACOT12 | c.575C>A p.P192H | Missense Mutation (SNP) | VAF 29/361 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201855173, COSV56896254, COSV56898401; called by muse, mutect2
- ACSM2A | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 26/196 reads (13%) | catalogued as rs146541514, COSV54586498; called by muse, mutect2, varscan2
- ACTB | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.029); catalogued as rs11546914; called by muse, mutect2, varscan2
- ADGRB2 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1019036110; called by muse, mutect2
- AMER3 | c.1476G>T p.E492D | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV58467942; called by muse, mutect2, varscan2
- AMHR2 | c.588G>C p.E196D | Missense Mutation (SNP) | VAF 93/511 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.268); catalogued as rs1447886200; called by muse, mutect2, varscan2
- AR | c.1768+1G>T p.X590_splice | Splice Site (SNP) | VAF 28/289 reads (10%) | catalogued as CS983691; called by muse, mutect2
- C2orf16 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 71/313 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as rs759896889, COSV68646865; called by muse, mutect2, varscan2
- C3 | c.2611G>T p.A871S | Missense Mutation (SNP) | VAF 88/426 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.263); catalogued as COSV99836682; called by muse, mutect2, varscan2
- C4B | c.3770C>T p.A1257V | Missense Mutation (SNP) | VAF 79/628 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1486742017; called by muse, mutect2, varscan2
- CDH10 | c.724A>T p.M242L | Missense Mutation (SNP) | VAF 115/545 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV52570171; called by muse, mutect2, varscan2
- CPLANE1 | c.7727C>A p.P2576Q | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV57066395; called by muse, mutect2, varscan2
- CPNE6 | c.1034del p.G345Efs*102 | Frame Shift Del (DEL) | VAF 100/334 reads (30%) | catalogued as COSV99393697; called by mutect2, pindel, varscan2
- CSMD3 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 60/375 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV52121298; called by muse, mutect2, varscan2
- DMD | c.7015C>A p.H2339N | Missense Mutation (SNP) | VAF 41/302 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100626469; called by muse, mutect2, varscan2
- DOCK4 | c.2132A>G p.Y711C | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs201322426; called by muse, mutect2, varscan2
- DSC1 | c.2438G>T p.R813I | Missense Mutation (SNP) | VAF 50/315 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57150723; called by muse, mutect2, varscan2
- EFCAB3 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 113/386 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59505454; called by muse, mutect2, varscan2
- EFNB1 | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 47/334 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as COSV52661059, COSV99214841; called by muse, mutect2, varscan2
- FAM153B | c.664+1G>A p.X222_splice (on ENST00000253490; = p.X145_splice on NM_001265615.1) | Splice Site (SNP) | VAF 62/537 reads (12%) | catalogued as rs1323721310, COSV53685495; called by muse, mutect2, varscan2
- IGHG3 | c.1125G>A p.P375= | Splice Region (SNP) | VAF 54/371 reads (15%) | catalogued as rs745576457; called by muse, varscan2
- KANK3 | c.727A>G p.K243E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs944203632; called by muse, mutect2
- KDM4E | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 23/363 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as rs782185063; called by muse, mutect2
- KNTC1 | c.5816G>A p.C1939Y | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV61084470; called by muse, mutect2
- LGSN | c.1321C>A p.P441T | Missense Mutation (SNP) | VAF 42/335 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV65727424; called by muse, mutect2, varscan2
- MESD | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 87/460 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99930925; called by muse, varscan2
- MLLT10 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs771824550; called by muse, mutect2, varscan2
- MUC5B | c.10631C>A p.T3544K | Missense Mutation (SNP) | VAF 125/608 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.22); catalogued as COSV101500658; called by muse, mutect2, varscan2
- MYBPC2 | c.3013C>T p.R1005* | Nonsense Mutation (SNP) | VAF 60/310 reads (19%) | catalogued as rs1364379290, COSV100731747, COSV100732043; called by muse, mutect2, varscan2
- MYH11 | c.3124C>T p.R1042W | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs774490005, COSV55547049; ClinVar: uncertain significance; called by muse, mutect2
- MYOM2 | c.2891+1G>A p.X964_splice | Splice Site (SNP) | VAF 40/121 reads (33%) | catalogued as rs1281268183; called by muse, mutect2, varscan2
- NFRKB | c.105A>T p.R35S (on ENST00000446488 / NM_001143835.2; = p.R48S on NM_006165.3) | Missense Mutation (SNP) | VAF 65/287 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs759904935, COSV58760221; called by muse, mutect2, varscan2
- NSUN3 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 51/320 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV58933620; called by muse, mutect2, varscan2
- OR5M8 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59118141; called by muse, mutect2, varscan2
- OR6X1 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772169276; called by muse, mutect2, varscan2
- RAMP3 | c.374T>C p.I125T | Missense Mutation (SNP) | VAF 132/544 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as rs781338436; called by muse, mutect2, varscan2
- RPS6KA6 | c.644C>G p.T215R | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53117841; called by muse, mutect2
- SDK2 | c.1444G>T p.G482W | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66182154; called by muse, mutect2, varscan2
- SEPTIN14 | c.478G>T p.V160L | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV66427733; called by muse, mutect2, varscan2
- SERPINB5 | c.91T>C p.S31P | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV66976055; called by muse, mutect2, varscan2
- SLC6A5 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 21/291 reads (7%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1383470600, COSV54228600; called by muse, mutect2
- STAC3 | c.432C>T p.I144= | Splice Region (SNP) | VAF 54/246 reads (22%) | catalogued as rs752436793, COSV60413872; called by muse, mutect2, varscan2
- TIAM1 | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 65/315 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as COSV54542593; called by muse, mutect2, varscan2
- TPD52 | c.278T>C p.L93P (on ENST00000379097 / NM_001025252.3; = p.L53P on NM_005079.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66950106; called by muse, mutect2, varscan2
- USP15 | c.1813A>G p.K605E (on ENST00000280377 / NM_001351159.2; = p.K576E on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.229); catalogued as rs1189479675; called by muse, mutect2
- WSCD1 | c.1201C>T p.R401W | Missense Mutation (SNP) | VAF 78/232 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs762766348, COSV58498491; called by muse, varscan2
- ZBED9 | c.2129G>A p.S710N | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1421010078; called by muse, mutect2
- ZNF462 | c.6745G>T p.E2249* | Nonsense Mutation (SNP) | VAF 110/407 reads (27%) | catalogued as COSV52930638; called by muse, mutect2, varscan2
- ADAMTS2 | c.702C>G p.D234E | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- ADGRL2 | c.2363G>C p.C788S (on ENST00000370717 / NM_001366005.1; = p.C775S on NM_012302.4) | Missense Mutation (SNP) | VAF 96/427 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- AGXT2 | c.301G>T p.G101* | Nonsense Mutation (SNP) | VAF 87/431 reads (20%) | called by muse, mutect2, varscan2
- ARHGAP21 | c.3911C>T p.P1304L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASXL2 | c.193A>G p.R65G | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATG2A | c.3364G>T p.D1122Y | Missense Mutation (SNP) | VAF 73/329 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATRX | c.4214+1G>T p.X1405_splice | Splice Site (SNP) | VAF 47/262 reads (18%) | called by muse, mutect2, varscan2
- BRD9 | c.644A>G p.Y215C | Missense Mutation (SNP) | VAF 235/731 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C6 | c.1828G>T p.D610Y | Missense Mutation (SNP) | VAF 113/561 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CAD | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- CARMIL3 | c.3170A>T p.H1057L | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- CCDC166 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CCM2 | c.1129G>T p.G377C | Missense Mutation (SNP) | VAF 179/647 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CCZ1B | c.1034T>A p.I345N | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CDC42BPG | c.2195G>T p.R732L | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- CDH10 | c.1396A>T p.N466Y | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CHAD | c.846G>C p.Q282H | Missense Mutation (SNP) | VAF 54/612 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.69); called by muse, mutect2
- CHL1 | c.1064A>T p.E355V (on ENST00000397491 / NM_001253387.1; = p.E371V on NM_006614.4) | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- COL25A1 | c.1201del p.D401Ifs*29 | Frame Shift Del (DEL) | VAF 42/333 reads (13%) | called by mutect2, pindel, varscan2
- CPLANE1 | c.7726C>A p.P2576T | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- CRACD | c.3140C>A p.A1047D | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- CREBRF | c.1486C>A p.L496I | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.978); called by muse, mutect2
- DCDC1 | c.5326C>A p.L1776M (on ENST00000597505 / NM_001367979.1; = p.L883M on NM_020869.3) | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DMD | c.5792G>T p.R1931M | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- EBF2 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ECHS1 | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 77/480 reads (16%) | called by muse, mutect2, varscan2
- ESPL1 | c.5714A>G p.E1905G | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- FGF23 | c.516del p.I173Yfs*18 | Frame Shift Del (DEL) | VAF 49/164 reads (30%) | called by mutect2, varscan2
- FRMPD4 | c.2289_2290del p.E764Dfs*15 | Frame Shift Del (DEL) | VAF 30/213 reads (14%) | called by mutect2, pindel, varscan2
- GFM1 | c.1973A>T p.N658I | Missense Mutation (SNP) | VAF 107/399 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GLRA3 | c.1004C>A p.A335E | Missense Mutation (SNP) | VAF 86/381 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRIA4 | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by muse, varscan2
- GTF3C3 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 40/368 reads (11%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.20C>A p.T7K | Missense Mutation (SNP) | VAF 62/296 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.132); called by muse, varscan2
- IGLV3-10 | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 108/433 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ITGB2 | c.1937G>T p.C646F (on ENST00000302347; = p.C622F on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- KAT6B | c.4451C>T p.S1484F | Missense Mutation (SNP) | VAF 143/938 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- KCNQ5 | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 31/294 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- KRTAP4-11 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 158/944 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.138); called by muse, varscan2
- LILRA4 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MAGEB10 | c.443A>T p.Q148L | Missense Mutation (SNP) | VAF 15/317 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.065); called by muse, mutect2
- MLLT10 | c.1255G>T p.G419C | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MMP16 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 49/238 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- MTARC1 | c.860G>T p.R287M | Missense Mutation (SNP) | VAF 87/435 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MUC17 | c.7022C>A p.T2341K | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- MYH7 | c.5688C>A p.F1896L | Missense Mutation (SNP) | VAF 179/633 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- MYH8 | c.4145C>A p.A1382D | Missense Mutation (SNP) | VAF 113/381 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MYO5A | c.945A>T p.L315= | Splice Region (SNP) | VAF 115/526 reads (22%) | called by muse, mutect2, varscan2
- MYT1L | c.2908C>A p.H970N | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NF2 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 69/620 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by muse, varscan2
- NMUR2 | c.1168A>T p.N390Y | Missense Mutation (SNP) | VAF 155/416 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- NOX4 | c.979G>T p.V327F | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- NUP205 | c.5732A>T p.Y1911F | Missense Mutation (SNP) | VAF 75/291 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- OBSCN | c.10357A>T p.T3453S | Missense Mutation (SNP) | VAF 125/568 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- OMP | c.69G>T p.R23S | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR14K1 | c.833T>C p.V278A | Missense Mutation (SNP) | VAF 102/501 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- OR4E2 | c.421T>A p.C141S | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- OR8S1 | c.1058_1059del p.A353Gfs*? | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | called by pindel, varscan2
- PCDH12 | c.992C>A p.P331H | Missense Mutation (SNP) | VAF 15/415 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- PCDHB7 | c.744G>T p.K248N | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PCSK1 | c.29G>A p.C10Y | Missense Mutation (SNP) | VAF 92/570 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLG | c.3560G>T p.R1187L | Missense Mutation (SNP) | VAF 148/691 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PRKCE | c.836A>T p.N279I | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKX | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PRR12 | c.1984C>G p.P662A (on ENST00000615927; = p.P1483A on NM_020719.3) | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PSMB8 | c.293_295+25del p.X98_splice (on ENST00000374882 / NM_148919.4; = p.X94_splice on NM_004159.5) | Splice Site (DEL) | VAF 92/472 reads (19%) | called by mutect2, pindel
- RPL10L | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 213/762 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- SETBP1 | c.3409G>C p.V1137L | Missense Mutation (SNP) | VAF 101/618 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SIGLEC16 | c.618C>A p.H206Q | Missense Mutation (SNP) | VAF 20/230 reads (9%) | called by muse, varscan2
- SLC12A2 | c.3214A>T p.M1072L | Missense Mutation (SNP) | VAF 83/197 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SLC6A1 | c.1572G>T p.M524I | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLIT1 | c.1095T>A p.Y365* | Nonsense Mutation (SNP) | VAF 66/246 reads (27%) | called by muse, mutect2, varscan2
- SPACA1 | c.638C>A p.P213Q | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SYNJ2 | c.2035T>C p.F679L | Missense Mutation (SNP) | VAF 72/333 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TNFRSF11A | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 114/590 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.30223G>T p.E10075* (on ENST00000591111; = p.E9148* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | called by muse, varscan2
- USP51 | c.213C>A p.N71K | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- ZAN | c.4637G>C p.G1546A | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFYVE19 | c.1312G>A p.D438N (on ENST00000355341 / NM_001077268.2; = p.D428N on NM_032850.5) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF492 | c.685G>C p.E229Q | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ZNF536 | c.1176G>T p.M392I | Missense Mutation (SNP) | VAF 50/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF726 | c.2054G>C p.G685A | Missense Mutation (SNP) | VAF 44/235 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ZNF766 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ACTB | c.108G>T p.G36= | Silent (SNP) | VAF 37/179 reads (21%) | called by muse, mutect2, varscan2
- AKAP4 | c.1335T>C p.S445= | Silent (SNP) | VAF 23/202 reads (11%) | called by muse, mutect2, varscan2
- ALPP | c.783G>A p.A261= | Silent (SNP) | VAF 55/193 reads (28%) | catalogued as rs749165151; called by muse, mutect2, varscan2
- ANO2 | c.897G>T p.L299= (on ENST00000356134 / NM_001278597.3; = p.L303= on NM_001278596.3) | Silent (SNP) | VAF 45/178 reads (25%) | called by muse, mutect2, varscan2
- ASTN2 | c.1389G>T p.V463= (on ENST00000313400 / NM_001365069.1; = p.V412= on NM_014010.5) | Silent (SNP) | VAF 47/157 reads (30%) | called by muse, mutect2, varscan2
- AXDND1 | c.2901C>A p.V967= | Silent (SNP) | VAF 54/266 reads (20%) | called by muse, mutect2, varscan2
- CCDC50 | c.627G>T p.S209= | Silent (SNP) | VAF 46/181 reads (25%) | catalogued as rs199687225; called by muse, mutect2, varscan2
- CDCP2 | c.1326C>T p.C442= | Silent (SNP) | VAF 41/281 reads (15%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.3564C>A p.P1188= | Silent (SNP) | VAF 27/221 reads (12%) | called by muse, varscan2
- CRIP2 | c.381G>A p.P127= | Silent (SNP) | VAF 101/376 reads (27%) | catalogued as rs782264361; called by muse, mutect2, varscan2
- CSMD3 | c.8259T>C p.Y2753= | Silent (SNP) | VAF 14/351 reads (4%) | called by muse, mutect2
- DDX17 | c.2142C>T p.A714= | Silent (SNP) | VAF 101/400 reads (25%) | called by muse, mutect2, varscan2
- FBN2 | c.4350T>G p.V1450= | Silent (SNP) | VAF 88/472 reads (19%) | called by mutect2, varscan2
- FKBP9 | c.636G>T p.G212= | Silent (SNP) | VAF 91/274 reads (33%) | catalogued as rs754479709; called by muse, mutect2, varscan2
- HIP1 | c.1731G>T p.R577= | Silent (SNP) | VAF 88/318 reads (28%) | called by muse, mutect2, varscan2
- KLF11 | c.375C>G p.P125= | Silent (SNP) | VAF 32/176 reads (18%) | catalogued as rs1339867879; called by muse, varscan2
- MUC16 | c.21087C>A p.T7029= | Silent (SNP) | VAF 71/322 reads (22%) | called by muse, mutect2, varscan2
- MUTYH | c.369G>T p.R123= | Silent (SNP) | VAF 119/800 reads (15%) | catalogued as rs1232031176; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYT1L | c.2907C>A p.S969= | Silent (SNP) | VAF 38/212 reads (18%) | catalogued as COSV101217326; called by muse, mutect2, varscan2
- NAAA | c.657G>T p.L219= | Silent (SNP) | VAF 68/282 reads (24%) | called by muse, mutect2, varscan2
- NANOGNB | c.381C>G p.P127= | Silent (SNP) | VAF 46/134 reads (34%) | called by muse, mutect2, varscan2
- NIBAN1 | c.1645C>T p.L549= | Silent (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- NLRP10 | c.576C>A p.T192= | Silent (SNP) | VAF 73/410 reads (18%) | catalogued as rs138681119, COSV100149868; called by muse, mutect2, varscan2
- OR4C6 | c.753C>T p.P251= | Silent (SNP) | VAF 79/361 reads (22%) | called by muse, mutect2, varscan2
- OTOF | c.1038G>A p.S346= | Silent (SNP) | VAF 102/606 reads (17%) | catalogued as rs750046776, COSV55498885; called by muse, mutect2, varscan2
- P2RY10 | c.405C>G p.L135= | Silent (SNP) | VAF 49/295 reads (17%) | called by muse, mutect2, varscan2
- PANX3 | c.207C>T p.P69= | Silent (SNP) | VAF 30/158 reads (19%) | called by muse, mutect2, varscan2
- PCDHA2 | c.1623C>A p.G541= | Silent (SNP) | VAF 290/748 reads (39%) | catalogued as COSV65370601; called by muse, mutect2, varscan2
- RIN1 | c.993G>C p.R331= | Silent (SNP) | VAF 37/122 reads (30%) | catalogued as COSV60925537; called by muse, mutect2, varscan2
- SALL1 | c.1728C>A p.A576= | Silent (SNP) | VAF 31/160 reads (19%) | called by muse, mutect2, varscan2
- SLC17A6 | c.654C>A p.S218= | Silent (SNP) | VAF 53/263 reads (20%) | catalogued as COSV54136536; called by muse, mutect2, varscan2
- SLC19A3 | c.285G>T p.L95= | Silent (SNP) | VAF 38/287 reads (13%) | called by muse, mutect2, varscan2
- SMARCA1 | c.573G>A p.L191= | Silent (SNP) | VAF 72/647 reads (11%) | called by muse, mutect2, varscan2
- ZNF285 | c.912C>G p.P304= | Silent (SNP) | VAF 12/222 reads (5%) | catalogued as COSV58408454; called by muse, mutect2
- ZNF556 | c.1002G>A p.A334= | Silent (SNP) | VAF 86/346 reads (25%) | catalogued as rs373920533; called by muse, mutect2, varscan2
- ANKRD26P1 | n.887C>A | RNA (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- ANKRD26P1 | n.886C>A | RNA (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- BTN2A3P | n.201G>T | RNA (SNP) | VAF 104/529 reads (20%) | called by muse, mutect2, varscan2
- C8orf87 | n.288G>A | RNA (SNP) | VAF 20/490 reads (4%) | called by muse, mutect2
- CACNA1G | c.4422+208G>A | Intron (SNP) | VAF 16/181 reads (9%) | catalogued as rs199892912; called by muse, mutect2
- CASP8 | c.1-8240A>T | Intron (SNP) | VAF 55/389 reads (14%) | called by muse, varscan2
- CFAP61 | c.2503+2324A>T | Intron (SNP) | VAF 22/364 reads (6%) | catalogued as rs758041959; called by muse, mutect2
- CHST13 | c.-11C>A | 5'UTR (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- CYP19A1 | c.1263+29G>A | Intron (SNP) | VAF 69/348 reads (20%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.-1C>T | 5'UTR (SNP) | VAF 32/311 reads (10%) | catalogued as COSV64421102; called by muse, mutect2, varscan2
- ETDB | chrX:135123392 G>T | 5'Flank (SNP) | VAF 42/454 reads (9%) | called by muse, mutect2, varscan2
- FLNC | c.5668+44G>A | Intron (SNP) | VAF 143/465 reads (31%) | called by muse, mutect2, varscan2
- GH1 | c.172-15C>T | Intron (SNP) | VAF 116/399 reads (29%) | catalogued as rs777334813; called by muse, mutect2, varscan2
- HS6ST2 | c.948-40082C>A | Intron (SNP) | VAF 35/379 reads (9%) | catalogued as COSV63713544; called by muse, mutect2
- KRT77 | c.544-349G>T | Intron (SNP) | VAF 68/402 reads (17%) | catalogued as rs918198220; called by muse, mutect2, varscan2
- LINC02876 | n.147C>A | RNA (SNP) | VAF 36/213 reads (17%) | catalogued as rs771781726; called by muse, mutect2, varscan2
- RPL7A | c.-8C>T | 5'UTR (SNP) | VAF 67/228 reads (29%) | catalogued as rs1488377910, COSV100034857; called by muse, mutect2, varscan2
- RTBDN | c.462+150G>T | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs1407999614; called by muse, mutect2, varscan2
- SLC6A10P | n.3766G>T | RNA (SNP) | VAF 46/196 reads (23%) | called by muse, mutect2, varscan2
- SYP | c.103-24C>A | Intron (SNP) | VAF 24/250 reads (10%) | called by muse, mutect2
- TRIM15 | c.*283C>T | 3'UTR (SNP) | VAF 10/69 reads (14%) | catalogued as rs1324285300; called by muse, mutect2, varscan2
- WDR13 | c.831+37G>T | Intron (SNP) | VAF 22/135 reads (16%) | called by muse, mutect2, varscan2
- WNT3A | c.-27C>T | 5'UTR (SNP) | VAF 42/205 reads (20%) | catalogued as rs757978719; called by mutect2, varscan2
